Somatic mutation profile of tumor specimen TCGA-91-6830-01A (aliquot TCGA-91-6830-01A-11D-1945-08) from TCGA case TCGA-91-6830, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.5 years (23,922 days).
Specimen TCGA-91-6830-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b20c8bb-861b-4137-b7a8-02d1ab03c646.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-91-6830-11A (Solid Tissue Normal), aliquot TCGA-91-6830-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09400a18-aff7-4b9d-ac61-c65239c28b11

The open-access MAF lists 229 somatic variants for this specimen: 170 protein-altering or splice-affecting, 56 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 56, Nonsense Mutation 11, Splice Site 5, Frame Shift Ins 4, Frame Shift Del 3, Splice Region 2, RNA 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF3 | c.1558C>A p.R520S | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53054148; called by muse, mutect2, varscan2
- ABHD2 | c.371-2A>T p.X124_splice | Splice Site (SNP) | VAF 12/64 reads (19%) | catalogued as COSV61775722; called by muse, mutect2, varscan2
- ADCY7 | c.2411T>C p.V804A | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV54269803; called by muse, mutect2, varscan2
- ADRB2 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 12/115 reads (10%) | catalogued as COSV60005312, COSV60006051; called by muse, mutect2, varscan2
- ANKRD22 | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.679); catalogued as rs748826411, COSV64237285; called by muse, mutect2
- ANKRD30A | c.2020G>A p.E674K (on ENST00000611781; = p.E618K on NM_052997.2) | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.678); catalogued as COSV64617755; called by muse, mutect2, varscan2
- ARAP3 | c.2995C>T p.R999C | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.825); catalogued as rs1464135643, COSV53353646; called by muse, mutect2
- ARHGAP5 | c.2140C>T p.L714F | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61536876, COSV61538587; called by muse, mutect2, varscan2
- ARHGEF10 | c.3806G>A p.G1269E (on ENST00000398564; = p.G1244E on NM_014629.4) | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs897540616, COSV50668733; called by muse, mutect2, varscan2
- ATP10B | c.2167G>C p.D723H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59161707; called by muse, mutect2
- ATP12A | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | catalogued as COSV54520921; called by muse, mutect2, varscan2
- ATP2C1 | c.2060C>T p.S687F | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.374); catalogued as COSV60761106; called by muse, mutect2
- ATP9A | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.811); catalogued as COSV58770460; called by muse, mutect2
- BEND3 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.956); catalogued as COSV64681942; called by muse, mutect2
- BHMT2 | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.166); catalogued as COSV54874209; called by muse, mutect2
- BST2 | c.29G>C p.R10T | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as COSV53089546, COSV53089833; called by muse, mutect2, varscan2
- BUD23 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV56095963; called by muse, mutect2
- CCDC39 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV56491095; called by muse, mutect2, varscan2
- CCDC60 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV59548592; called by muse, mutect2, varscan2
- CLEC9A | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV63351306; called by muse, mutect2, varscan2
- CMTM5 | c.143T>A p.I48N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV59307390; called by muse, mutect2, varscan2
- COG8 | c.1338C>G p.F446L | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.279); catalogued as COSV54743177; called by muse, mutect2
- COL19A1 | c.2321G>C p.G774A | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59583479; called by muse, mutect2, varscan2
- CREBBP | c.5129G>C p.C1710S | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM162096, COSV52136168; called by muse, mutect2
- CTTNBP2 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778052265, COSV50392847; called by muse, mutect2, varscan2
- CYB5D2 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.665); catalogued as COSV56801859; called by mutect2, varscan2
- CYP2E1 | c.126C>G p.I42M | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV53312852, COSV53314820; called by muse, mutect2, varscan2
- DCUN1D1 | c.94C>G p.Q32E | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV53043732, COSV53045794; called by muse, mutect2
- DHX36 | c.1616G>C p.R539T | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as COSV57672456, COSV57676064; called by muse, mutect2, varscan2
- DKC1 | c.857T>C p.V286A | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV65777989; called by muse, mutect2
- DNM1 | c.727G>T p.D243Y | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.882); catalogued as COSV100359930, COSV57855116; called by muse, varscan2
- DNM1 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as rs755625989, COSV57848382, COSV57851712; called by muse, varscan2
- DNM1 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57855148; called by muse, mutect2, varscan2
- DNMT3A | c.327dup p.Q110Afs*14 | Frame Shift Ins (INS) | VAF 7/45 reads (16%) | catalogued as rs1446314200; called by mutect2, pindel, varscan2
- DOCK11 | c.5001G>C p.K1667N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.275); catalogued as COSV52245591; called by muse, mutect2, varscan2
- DTNB | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as rs961850767, COSV56482396; called by muse, mutect2
- DTNB | c.1077G>C p.K359N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.258); catalogued as COSV56482409; called by muse, mutect2, varscan2
- DYNC1H1 | c.7530G>A p.M2510I | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV64140770; called by muse, mutect2
- EEF2K | c.1097C>G p.S366C | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV53783297, COSV53785767; called by muse, mutect2
- EFR3A | c.1708G>T p.D570Y | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54453697, COSV54461168; called by muse, mutect2, varscan2
- EIF6 | c.11G>C p.R4P | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65584067; called by muse, mutect2, varscan2
- EML1 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV51749552, COSV51750691; called by muse, mutect2, varscan2
- ERICH3 | c.1861C>G p.Q621E | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.647); catalogued as COSV58598332, COSV58614939; called by muse, mutect2
- FGD4 | c.1066G>C p.E356Q | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56788124; called by muse, mutect2, varscan2
- FNDC3B | c.1644G>A p.L548= | Splice Region (SNP) | VAF 11/107 reads (10%) | catalogued as COSV100395169, COSV61047651; called by muse, mutect2, varscan2
- G6PC2 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 10/79 reads (13%) | catalogued as COSV56372029; called by muse, mutect2, varscan2
- GAD1 | c.713G>A p.G238E | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60153741; called by muse, mutect2, varscan2
- GAN | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.113); catalogued as COSV73721258; called by muse, mutect2, varscan2
- GGA2 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 27/201 reads (13%) | catalogued as COSV100564591, COSV59170068; called by muse, mutect2, varscan2
- GPRIN1 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as rs1003304520, COSV56143524; called by muse, mutect2
- GREB1 | c.2173C>G p.L725V | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV52186664; called by muse, mutect2
- GSDMC | c.797C>G p.S266C | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV52698085; called by muse, mutect2
- GSKIP | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as COSV68451449; called by muse, mutect2
- HBP1 | c.1509G>C p.K503N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51760879; called by muse, mutect2, varscan2
- HECTD1 | c.3835C>T p.R1279C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780660891, COSV67948561; called by mutect2, varscan2
- HIRIP3 | c.516G>T p.R172S | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs374834653; called by muse, mutect2
- HIVEP1 | c.4271G>C p.R1424T | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65104179; called by muse, mutect2
- HK2 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.079); catalogued as COSV51878318; called by muse, mutect2, varscan2
- HLA-C | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV66117565; called by muse, mutect2, varscan2
- HSPA4 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as COSV59183325; called by muse, mutect2
- IFNB1 | c.95G>A p.R32K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.166); catalogued as COSV66525624; called by muse, mutect2, varscan2
- IFNGR1 | c.982C>G p.P328A | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.158); catalogued as COSV62992524; called by muse, mutect2, varscan2
- IGDCC3 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV60079393; called by muse, mutect2, varscan2
- IGDCC3 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.249); catalogued as rs573108336, COSV60079405; called by muse, varscan2
- IMPA1 | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.277); catalogued as COSV56272601; called by muse, mutect2
- INSR | c.2797A>T p.N933Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.733); catalogued as COSV57170551; called by muse, mutect2, varscan2
- IPO13 | c.1959C>G p.I653M | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as COSV64894914; called by muse, mutect2
- ITGAL | c.2497G>C p.E833Q | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.417); catalogued as COSV63323681; called by muse, mutect2
- ITGBL1 | c.866C>A p.S289* | Nonsense Mutation (SNP) | VAF 13/135 reads (10%) | catalogued as COSV66010985; called by muse, mutect2, varscan2
- KMT2C | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV51321473, COSV51484816; called by muse, varscan2
- KRTAP5-3 | c.637T>A p.C213S | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV68791103; called by muse, varscan2
- LCLAT1 | c.263G>T p.W88L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV58372985, COSV58377028; called by muse, mutect2, varscan2
- LLGL1 | c.911A>G p.H304R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.575); catalogued as COSV57499941; called by muse, mutect2, varscan2
- LRP4 | c.3365-2A>T p.X1122_splice | Splice Site (SNP) | VAF 10/72 reads (14%) | catalogued as COSV66137908; called by muse, mutect2, varscan2
- LRRC41 | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.953); catalogued as COSV58439085, COSV58440104; called by muse, mutect2
- LRRK1 | c.3649G>A p.E1217K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as COSV52623274; called by muse, varscan2
- MAP7D3 | c.318G>T p.M106I | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV60172075; called by muse, mutect2, varscan2
- MARVELD3 | c.1099G>C p.A367P | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs766427811, COSV51705631; called by muse, mutect2, varscan2
- MCM5 | c.1214C>G p.S405C | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53347774; called by muse, mutect2, varscan2
- MDN1 | c.12115G>C p.E4039Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as COSV65523303; called by muse, mutect2
- MECP2 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV57656108; called by muse, mutect2, varscan2
- MED12 | c.5848C>T p.H1950Y | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.391); catalogued as COSV61351754; called by muse, mutect2
- MEIS2 | c.873G>A p.M291I (on ENST00000561208 / NM_170675.5; = p.M278I on NM_002399.3) | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV54942708; called by muse, mutect2, varscan2
- METTL14 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as COSV66311043; called by muse, mutect2, varscan2
- MICALL1 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53242722; called by muse, mutect2, varscan2
- MIER3 | c.871G>C p.E291Q (on ENST00000381199 / NM_001297599.2; = p.E290Q on NM_152622.4) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67083267; called by muse, mutect2, varscan2
- MIS12 | c.313A>G p.K105E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV50147770; called by muse, mutect2, varscan2
- MME | c.334G>C p.D112H | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100852519, COSV64709539; called by muse, mutect2, varscan2
- NF2 | c.863C>G p.S288* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV58523216; called by muse, mutect2
- NPAP1 | c.2050A>T p.S684C | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as COSV61510149; called by muse, mutect2, varscan2
- NTF3 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV58418195; called by muse, mutect2, varscan2
- OCEL1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.269); catalogued as COSV53044929; called by muse, mutect2
- OR2M4 | c.554T>A p.L185* | Nonsense Mutation (SNP) | VAF 16/106 reads (15%) | catalogued as COSV100141152; called by muse, varscan2
- OR4K13 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as rs761795290, COSV59858866, COSV59860197; called by muse, mutect2, varscan2
- OTOGL | c.2220C>G p.F740L (on ENST00000547103; = p.F731L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV101509202; called by muse, mutect2
- PAK1 | c.1000T>G p.Y334D | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53700015; called by muse, mutect2, varscan2
- PAPPA2 | c.4858C>T p.L1620F | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV62790832, COSV62808027; called by muse, mutect2, varscan2
- PCLO | c.11132T>C p.M3711T | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV61657909; called by muse, mutect2, varscan2
- PDCD7 | c.932A>T p.D311V | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1379806312, COSV52601206; called by muse, mutect2, varscan2
- PDE1C | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as rs768497187, COSV58524849; called by muse, mutect2, varscan2
- PEX13 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54371172; called by muse, mutect2
- PEX6 | c.2747C>G p.S916C | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV55104859; called by muse, mutect2
- PLXNB2 | c.4255G>T p.E1419* | Nonsense Mutation (SNP) | VAF 13/102 reads (13%) | catalogued as COSV63783714; called by muse, mutect2, varscan2
- PPIP5K2 | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58608594; called by muse, mutect2, varscan2
- PRDX5 | c.496G>C p.D166H | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50007697; called by muse, mutect2
- PRR5L | c.376G>C p.A126P | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV61122992; called by muse, mutect2, varscan2
- PTP4A3 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV61472549; called by muse, mutect2
- PTPN9 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as COSV60722717; called by muse, mutect2, varscan2
- RAP2B | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60257412; called by muse, mutect2, varscan2
- RASSF1 | c.475-1G>C p.X159_splice (on ENST00000357043 / NM_170714.2; = p.X155_splice on NM_007182.5) | Splice Site (SNP) | VAF 4/36 reads (11%) | catalogued as COSV51701503, COSV51701776; called by muse, mutect2
- RBM41 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.449); catalogued as COSV52564801; called by muse, mutect2, varscan2
- RFWD3 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.197); catalogued as COSV63098952; called by muse, mutect2
- RGS3 | c.618C>T p.F206= (on ENST00000350696 / NM_001282923.2; = p.F94= on NM_017790.4) | Splice Region (SNP) | VAF 6/60 reads (10%) | catalogued as COSV58284099; called by mutect2, varscan2
- RPGRIP1L | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50913795; called by muse, mutect2
- RPL36AL | c.179C>G p.A60G | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as COSV53564680; called by muse, mutect2, varscan2
- RTL9 | c.1409C>A p.A470D | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.463); catalogued as COSV71826110; called by muse, mutect2, varscan2
- RTN4 | c.1135C>G p.P379A | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV58272221; called by muse, mutect2, varscan2
- SCAF1 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs146838422, COSV100862191; called by muse, mutect2, varscan2
- SENP7 | c.1513G>C p.E505Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.559); catalogued as COSV58608570, COSV58616756; called by muse, mutect2, varscan2
- SFMBT2 | c.1921A>C p.S641R | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV62814682; called by muse, mutect2, varscan2
- SIPA1L3 | c.5080G>C p.E1694Q | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.306); catalogued as COSV55921832; called by muse, mutect2, varscan2
- SLC26A3 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1467858471, COSV60642000; called by muse, mutect2, varscan2
- SLITRK2 | c.2044G>C p.G682R | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); catalogued as COSV100157654, COSV59422638, COSV59427826; called by muse, mutect2
- SLITRK2 | c.2045G>T p.G682V | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV59423055; called by muse, mutect2
- SPATA22 | c.326G>C p.W109S | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as COSV52153910; called by muse, mutect2, varscan2
- SPTA1 | c.6224T>A p.L2075Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100934787; called by muse, mutect2, varscan2
- SPTA1 | c.2384T>A p.L795Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV63757622; called by muse, mutect2, varscan2
- STAB1 | c.6727C>G p.L2243V | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58741356; called by muse, mutect2, varscan2
- STAB1 | c.7014C>G p.F2338L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV58741363; called by muse, mutect2, varscan2
- STAB2 | c.6650G>C p.R2217T | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV66344726; called by muse, mutect2
- SYNE4 | c.1151A>T p.H384L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV61010880; called by muse, mutect2, varscan2
- TCHH | c.5647G>A p.E1883K | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.539); catalogued as COSV64277063; called by muse, mutect2, varscan2
- THBS2 | c.1623G>C p.Q541H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV64681438, COSV64682146; called by muse, mutect2, varscan2
- TMEM132B | c.2308C>A p.Q770K | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV54748622, COSV54765265; called by muse, mutect2, varscan2
- TMEM169 | c.440G>C p.R147T | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as COSV55266348; called by muse, mutect2
- TMEM256 | c.124G>C p.D42H | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV56658557; called by muse, mutect2
- TRANK1 | c.7100A>T p.E2367V | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.368); catalogued as COSV57160847; called by muse, mutect2, varscan2
- TSC22D2 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as rs893120628, COSV100721209; called by muse, mutect2
- TTLL4 | c.2247G>C p.Q749H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51438626; called by muse, mutect2
- TTN | c.80542G>A p.E26848K (on ENST00000591111; = p.E19424K on NM_003319.4) | Missense Mutation (SNP) | VAF 3/36 reads (8%) | PolyPhen probably damaging (0.994); catalogued as COSV60031266, COSV60265292; called by muse, mutect2
- TULP1 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs1432886863, COSV57693586; called by muse, mutect2
- TULP1 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.391); catalogued as COSV57693591; called by muse, mutect2
- UBA2 | c.1596C>G p.I532M | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV55829801; called by muse, mutect2
- UBN2 | c.2726C>G p.S909C | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.987); catalogued as COSV56033284, COSV56034383; called by muse, mutect2, varscan2
- USF1 | c.262C>G p.Q88E | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.472); catalogued as COSV57039898; called by muse, mutect2, varscan2
- USP40 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52486549; called by muse, mutect2, varscan2
- UTRN | c.3180+1G>A p.X1060_splice | Splice Site (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100839851; called by muse, mutect2
- XIRP2 | c.1610A>G p.E537G (on ENST00000628543; = p.E712G on NM_152381.6) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54725592; called by muse, mutect2, varscan2
- YARS1 | c.1335-1G>C p.X445_splice | Splice Site (SNP) | VAF 5/60 reads (8%) | catalogued as COSV65113489, COSV65114900; called by muse, mutect2
- YWHAQ | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.739); catalogued as COSV53004340; called by muse, mutect2, varscan2
- ZBTB4 | c.3017G>C p.R1006T | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as COSV60141835; called by muse, mutect2
- ZBTB48 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.191); catalogued as COSV59840203, COSV59840442; called by muse, mutect2, varscan2
- ZC3H12C | c.1376C>G p.A459G | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV53711654; called by muse, mutect2, varscan2
- ZCCHC8 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs753378950, COSV60317582; called by muse, mutect2
- ZFYVE16 | c.647C>G p.S216* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV62017040; called by muse, mutect2, varscan2
- ZMIZ1 | c.50G>C p.C17S | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV57901777; called by muse, mutect2
- ZNF138 | c.823G>A p.E275K (on ENST00000307355 / NM_001367572.1; = p.E249K on NM_006524.4) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as COSV100245731, COSV56465620; called by muse, mutect2, varscan2
- ZNF221 | c.117C>G p.F39L | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52110710; called by muse, mutect2
- ZNF320 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.085); catalogued as COSV67088740; called by muse, mutect2, varscan2
- ZNF334 | c.1410C>G p.F470L | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as COSV61619761; called by muse, mutect2
- ZNF592 | c.935C>G p.S312* | Nonsense Mutation (SNP) | VAF 6/102 reads (6%) | catalogued as COSV55436345, COSV55438861; called by muse, mutect2
- ZNF646 | c.2827C>T p.Q943* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV54926059; called by muse, mutect2
- CCDC120 | c.1291del p.R431Efs*203 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, pindel
- CGRRF1 | c.349dup p.C117Lfs*16 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by mutect2, pindel, varscan2
- HCRTR1 | c.1221dup p.I408Hfs*6 | Frame Shift Ins (INS) | VAF 14/142 reads (10%) | called by mutect2, pindel, varscan2
- KCTD5 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); called by mutect2, varscan2
- MGAT5 | c.1246del p.P416Lfs*17 | Frame Shift Del (DEL) | VAF 10/69 reads (14%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 42/400 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- ROS1 | c.4340del p.L1447Qfs*57 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | called by mutect2, pindel
- RYBP | c.203dup p.E69Gfs*7 | Frame Shift Ins (INS) | VAF 15/92 reads (16%) | called by mutect2, pindel, varscan2
- ABCA12 | c.2925C>G p.V975= (on ENST00000272895 / NM_173076.3; = p.V657= on NM_015657.3) | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs1192525262, COSV55971443; called by muse, mutect2, varscan2
- AMD1 | c.801G>C p.L267= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs766576695, COSV64387991; called by muse, mutect2
- APOA4 | c.366G>A p.Q122= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV63361042; called by muse, mutect2
- ARHGAP35 | c.441G>A p.Q147= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV68334531; called by muse, mutect2, varscan2
- ASPSCR1 | c.1227C>A p.P409= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as COSV100145005, COSV60730606; called by muse, mutect2
- ATP8B4 | c.2874C>T p.C958= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs376725309, COSV52711292; called by muse, mutect2, varscan2
- BAP1 | c.1818C>T p.A606= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1553644724, COSV99963858; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC189 | c.345G>A p.L115= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV60313363; called by muse, mutect2, varscan2
- CHAT | c.1581G>A p.Q527= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV60330700; called by muse, mutect2
- CSMD1 | c.8301G>T p.T2767= (on ENST00000520002; = p.T2766= on NM_033225.6) | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs765938760, COSV59315997, COSV59328648, COSV59361465; called by muse, mutect2, varscan2
- CUBN | c.8877C>T p.L2959= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV64724119; called by muse, mutect2
- CYP2A13 | c.741C>T p.F247= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV57836899, COSV57839561; called by muse, mutect2, varscan2
- DHX9 | c.481C>T p.L161= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV62361394; called by muse, mutect2, varscan2
- DSG1 | c.3051T>C p.S1017= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV57138463; called by muse, mutect2, varscan2
- EPHB6 | c.2412G>T p.V804= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as COSV63893157; called by muse, mutect2
- EXOSC4 | c.258C>T p.R86= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as COSV60156341; called by muse, mutect2
- GALNT5 | c.1608C>T p.D536= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV52040243; called by muse, mutect2, varscan2
- ICAM1 | c.1494C>T p.L498= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV53426616; called by muse, mutect2, varscan2
- KLHL11 | c.252G>A p.Q84= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV59862869; called by muse, mutect2
- LGR5 | c.2445C>G p.L815= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV57008722; called by muse, mutect2
- LRFN5 | c.810T>A p.T270= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as COSV53267891, COSV99983461; called by muse, mutect2, varscan2
- MAPK8IP3 | c.180G>A p.V60= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs567860523, COSV50188843; called by mutect2, varscan2
- MICALL1 | c.1056G>A p.P352= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs147560297; called by muse, varscan2
- MYO1C | c.2826C>T p.L942= (on ENST00000648651 / NM_001080779.2; = p.L907= on NM_033375.5) | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV62999049, COSV63000333; called by muse, mutect2, varscan2
- NAV3 | c.5184A>G p.S1728= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV57104064; called by muse, mutect2
- NEXMIF | c.1596C>G p.T532= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV99280581; called by muse, mutect2, varscan2
- NOS2 | c.924C>A p.V308= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV58226496; called by mutect2, varscan2
- NR4A1 | c.888G>A p.Q296= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs1421419170, COSV54486518; called by muse, mutect2, varscan2
- NUP205 | c.1767C>T p.I589= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV53664350; called by muse, mutect2, varscan2
- PAK2 | c.48G>A p.V16= | Silent (SNP) | VAF 15/161 reads (9%) | catalogued as COSV59084297; called by muse, mutect2
- PDZRN3 | c.1938C>T p.F646= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as rs377558165; called by muse, mutect2, varscan2
- PENK | c.453C>T p.A151= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV59242794; called by muse, mutect2, varscan2
- PLPPR5 | c.72G>A p.V24= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV54177240; called by muse, mutect2, varscan2
- PLTP | c.564C>G p.L188= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs1251132273, COSV62465862; called by muse, mutect2, varscan2
- POLG2 | c.486G>A p.L162= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as COSV56750712; called by muse, mutect2
- POU6F1 | c.1339C>T p.L447= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV61327562; called by muse, mutect2
- PROZ | c.900C>T p.L300= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs74115810, COSV61440081; called by muse, mutect2, varscan2
- PTCHD1 | c.207C>T p.L69= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV65060638, COSV65062275; called by muse, mutect2, varscan2
- RAPH1 | c.3507C>G p.L1169= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as COSV55587746; called by muse, mutect2
- RBM12B | c.66C>T p.F22= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs1451455388, COSV66968384; called by muse, mutect2, varscan2
- RPL7 | c.279C>T p.I93= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV53583878; called by muse, mutect2, varscan2
- SPTA1 | c.6225G>A p.L2075= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100934786; called by muse, mutect2, varscan2
- TENM4 | c.7626C>T p.L2542= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs747516983, COSV53658693; called by muse, mutect2, varscan2
- TMC5 | c.2619C>G p.L873= (on ENST00000396229 / NM_001105248.1; = p.L627= on NM_024780.5) | Silent (SNP) | VAF 11/153 reads (7%) | catalogued as COSV54908126; called by muse, mutect2
- TPRA1 | c.630C>A p.I210= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV56161667; called by muse, mutect2, varscan2
- TSC22D2 | c.636G>A p.A212= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV100721208; called by muse, mutect2
- TUBGCP2 | c.300G>A p.Q100= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV53307853; called by muse, mutect2, varscan2
- TUBGCP5 | c.3051C>G p.L1017= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- USP44 | c.66C>G p.L22= | Silent (SNP) | VAF 9/155 reads (6%) | catalogued as COSV51566220; called by muse, mutect2
- VGLL1 | c.93C>A p.T31= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as COSV65703739; called by muse, mutect2, varscan2
- ZC3H7A | c.2286C>T p.L762= | Silent (SNP) | VAF 16/183 reads (9%) | catalogued as rs1427030393, COSV63271058; called by muse, mutect2
- ZCCHC12 | c.810C>G p.L270= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV59572656; called by muse, mutect2, varscan2
- ZFP42 | c.555G>C p.L185= | Silent (SNP) | VAF 10/125 reads (8%) | catalogued as COSV58818846; called by muse, mutect2
- ZNF175 | c.1137C>T p.F379= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs201288733, COSV51797787; called by muse, mutect2, varscan2
- ZNF385A | c.465G>A p.E155= (on ENST00000338010 / NM_001130967.3; = p.E135= on NM_015481.3) | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV61493562, COSV61494673; called by muse, mutect2, varscan2
- ZNF605 | c.306G>A p.L102= | Silent (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- MIR758 | n.82C>G | RNA (SNP) | VAF 6/127 reads (5%) | called by muse, mutect2
- POLA1 | c.2947-21098A>T | Intron (SNP) | VAF 11/148 reads (7%) | catalogued as COSV66886847; called by muse, mutect2
- TFE3 | c.*179C>T | 3'UTR (SNP) | VAF 5/55 reads (9%) | catalogued as COSV100252518; called by muse, mutect2, varscan2
